Gene-level copy-number profile of tumor specimen ALCH-ADNI-TTP1-A from ALCHEMIST case ALCH-ADNI, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 47.9 years (17,508 days).
Specimen ALCH-ADNI-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file c322e2ce-1f9e-4257-b4b8-c2fdabb265f8.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-ADNI-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,237 have no estimate.
https://portal.gdc.cancer.gov/files/7975dcbf-4edc-46a7-9a1d-9b3c7d30b48e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 33; copy number 1: 1,169; copy number 2: 56,107; copy number 3: 973; copy number 4: 88; copy number 5: 7; copy number 6: 1; copy number 8: 3; copy number 22: 2; copy number 37: 3.

Homozygous deletions (total copy number 0; autosomes only): 33 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:3,487,246–3,611,508, 3 genes: AL512413.1, MEGF6, MIR551A.
- chr4:1,550,284–1,580,253, 2 genes: AC147067.2, AC147067.1.
- chr5:441,498–443,160, 1 gene (within-gene range 0–1): EXOC3-AS1.
- chr5:1,201,595–1,246,189, 2 genes: SLC6A19, SLC6A18.
- chr11:1,919,703–1,938,706, 1 gene: TNNT3.
- chr16:668,105–684,528, 6 genes (within-gene range 0–1): RHOT2, RHBDL1, LINC02867, Z92544.2, STUB1, JMJD8.
- chr16:2,088,708–2,135,898, 2 genes (within-gene range 0–2): PKD1, MIR1225.
- chr16:2,106,669–2,133,204, 5 genes: MIR6511B1, AC009065.6, AC009065.3, Y_RNA, MIR4516.
- chr16:2,155,698–2,196,605, 2 genes: TRAF7, CASKIN1.
- chr16:30,984,630–30,989,147, 2 genes (within-gene range 0–2): AC135048.4, HSD3B7.
- chr17:17,507,351–17,508,308, 1 gene (within-gene range 0–2): AC020558.2.
- chr18:79,900,555–79,900,903, 1 gene: AC114341.1.
- chr19:18,434,388–18,443,597, 2 genes (within-gene range 0–3): ISYNA1, AC010335.1.
- chr19:18,448,275–18,448,805, 2 genes (within-gene range 0–2): AC010335.2, AC010335.3.
- chr20:25,284,915–25,285,588, 1 gene (within-gene range 0–2): AL121772.3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 16 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:248,906,196–248,937,043, 3 genes, copy number 5: PGBD2, RNU6-1205P, RPL23AP25.
- chr14:18,333,726–18,412,264, 2 genes, copy number 5–6: CR383658.1, CR383658.2.
- chr22:18,400,407–18,524,935, 6 genes, copy number 5–8: PPP1R26P3, FAM230A, AC023490.2, FAM247B, GGTLC3, Metazoa_SRP.
- chr22:18,605,355–18,611,919, 3 genes, copy number 37: AC023490.1, RN7SKP131, RIMBP3.
- chr22:18,636,445–18,653,617, 2 genes, copy number 22: CA15P2, PPP1R26P2.

Autosomal genes at a single copy (total copy number 1): 1,169. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
